Somatic mutation profile of tumor specimen TCGA-FY-A4B4-01A (aliquot TCGA-FY-A4B4-01A-11D-A23U-08) from TCGA case TCGA-FY-A4B4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 62.5 years (22,830 days).
Specimen TCGA-FY-A4B4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5de1977-41bd-4628-8668-e7e963e2f253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A4B4-10A (Blood Derived Normal), aliquot TCGA-FY-A4B4-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76a1ea5c-acda-49ae-bbf7-bd6a3be1be4d

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DRD4 | c.554G>T p.C185F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99448608; called by muse, mutect2, varscan2
- EGFL8 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs1561836403, COSV100246907; called by muse, mutect2, varscan2
- HEXB | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54669004, COSV99784218; called by muse, mutect2, varscan2
- KDM2A | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1416519406, COSV100445521; called by muse, varscan2
- LINGO1 | c.1669C>G p.L557V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as COSV100796364; called by muse, mutect2, varscan2
- C2CD3 | c.3117C>T p.H1039= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV100486509; called by muse, mutect2, varscan2
- MAP1A | c.78C>G p.P26= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV100288529; called by muse, mutect2, varscan2
- OR4D11 | c.687A>C p.A229= | Silent (SNP) | VAF 73/190 reads (38%) | catalogued as COSV100506530; called by muse, mutect2, varscan2
- PIK3R6 | c.2091T>A p.T697= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100266392; called by muse, mutect2, varscan2
